Somatic mutation profile of tumor specimen TCGA-26-1442-01A (aliquot TCGA-26-1442-01A-01D-1696-08) from TCGA case TCGA-26-1442, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 43.7 years (15,950 days).
Specimen TCGA-26-1442-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76a94ade-d420-4691-bb3a-c928a2a788da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-26-1442-10A (Blood Derived Normal), aliquot TCGA-26-1442-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/935f45b4-5061-40e9-952e-9b402a535685

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 28, Silent 12, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/53 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 18/30 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- ACOT8 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754407700, COSV54169727; called by muse, mutect2, varscan2
- CDHR1 | c.1709A>G p.N570S | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1217171514, COSV60562877; called by muse, mutect2, varscan2
- CFHR4 | c.1543T>C p.C515R (on ENST00000367416 / NM_001201551.2; = p.C269R on NM_006684.5) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV52229540; called by muse, mutect2, varscan2
- DLG5 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748210887, COSV64948254; called by muse, mutect2, varscan2
- ESPL1 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 99/610 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV57759817, COSV57760246; called by muse, mutect2, varscan2
- H1-6 | c.596A>T p.N199I | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1561950637, COSV58090653, COSV58091502; called by muse, mutect2
- IRAG1 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as rs368754767; called by muse, mutect2, varscan2
- ITGA7 | c.2565-2A>G p.X855_splice (on ENST00000555728; = p.X811_splice on NM_002206.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 7/56 reads (13%) | catalogued as COSV57695985; called by muse, mutect2, varscan2
- ITIH1 | c.2005G>A p.V669M | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746112878, COSV56255533; called by muse, mutect2, varscan2
- KDM5C | c.3493C>T p.R1165C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64762691; called by muse, mutect2, varscan2
- KIF5C | c.2323G>C p.D775H | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV68480245, COSV68481400; called by muse, mutect2, varscan2
- LMNB2 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1482737201, COSV57588294; called by muse, varscan2
- MIB1 | c.109G>C p.G37R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211020670, COSV55091089, COSV55095635; called by muse, mutect2
- MS4A8 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs572019233, COSV55753990; called by muse, varscan2
- MTERF2 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs199833664, COSV53527727; called by muse, mutect2, varscan2
- NCOA7 | c.1301A>T p.D434V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.125); catalogued as COSV57655869; called by muse, mutect2, varscan2
- NYNRIN | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1452634221, COSV66842842; called by muse, mutect2
- PGLS | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs143569199; called by muse, mutect2, varscan2
- SOCS6 | c.592A>G p.N198D | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1236274790, COSV67546481; called by muse, mutect2, varscan2
- SP1 | c.2230A>T p.I744F (on ENST00000327443 / NM_138473.3; = p.I737F on NM_003109.1) | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV59403131; called by muse, mutect2, varscan2
- SPATA31E1 | c.548A>G p.D183G | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.654); catalogued as COSV57792141, COSV57792761; called by muse, mutect2, varscan2
- TEX26 | c.440C>G p.T147S | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.921); catalogued as COSV66839968; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1758G>T p.E586D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.109); catalogued as COSV61456176; called by muse, mutect2, varscan2
- TRPM5 | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149949624, COSV50152020; called by muse, mutect2, varscan2
- USH2A | c.4420C>G p.L1474V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV56377060; called by muse, mutect2
- ZBTB38 | c.1733A>G p.Y578C | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs747459711, COSV58540119; called by muse, mutect2, varscan2
- ZNF233 | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV61933757; called by muse, mutect2, varscan2
- AK1 | c.425dup p.N142Kfs*2 | Frame Shift Ins (INS) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- COQ10B | c.84G>A p.Q28= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as COSV55836432; called by muse, mutect2, varscan2
- DNAH9 | c.8088T>C p.C2696= | Silent (SNP) | VAF 39/70 reads (56%) | catalogued as COSV52352325; called by muse, mutect2, varscan2
- EIF2B1 | c.66A>G p.S22= | Silent (SNP) | VAF 12/228 reads (5%) | catalogued as COSV57459031; called by muse, mutect2
- ERLIN2 | c.924T>C p.S308= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs574464016, COSV52420952; called by mutect2, varscan2
- OGDH | c.2889A>G p.Q963= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as rs1171160610, COSV56050751; called by muse, mutect2
- OR52B6 | c.204C>A p.V68= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV61447887; called by muse, mutect2, varscan2
- PEG3 | c.1410C>T p.H470= | Silent (SNP) | VAF 60/88 reads (68%) | catalogued as COSV55635484, COSV55644666; called by muse, mutect2, varscan2
- PFKM | c.912G>A p.T304= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as rs764516934, COSV56657706; called by muse, mutect2, varscan2
- SHCBP1L | c.489T>A p.T163= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV62355224; called by muse, mutect2, varscan2
- SMARCC1 | c.732C>T p.V244= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV54381205; called by muse, mutect2
- TIE1 | c.1788C>T p.N596= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs761797941, COSV65249680; called by muse, mutect2, varscan2
- TRIML1 | c.897C>T p.L299= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as rs201972598, COSV60193494, COSV60195535; called by muse, mutect2
